Somatic mutation profile of tumor specimen TARGET-10-PANXLR-09A (aliquot TARGET-10-PANXLR-09A-01D) from TARGET case TARGET-10-PANXLR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (719 days).
Specimen TARGET-10-PANXLR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1fb842b-e272-4e71-9e6f-3f1218d460eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXLR-10A (Blood Derived Normal), aliquot TARGET-10-PANXLR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d90920a0-d127-48e4-a393-84e0b2c022fe

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV104379009; called by muse, mutect2, varscan2
- KSR2 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56667168; called by muse, mutect2
- SULT4A1 | c.508+1G>A p.X170_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as rs1300942161; called by muse, mutect2
- TSHZ2 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4orf17 | c.774C>A p.P258= | Silent (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- IGF2BP2 | c.1458C>T p.F486= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV60486173; called by muse, mutect2, varscan2
- KRT20 | c.246G>A p.A82= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs753053653, COSV51424844; called by muse, mutect2, varscan2
- NLRP7 | c.210G>A p.A70= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs111764628, COSV60177080; called by muse, mutect2, varscan2
- CRBN | c.751-41A>C | Intron (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- FAM98A | c.523-22T>C | Intron (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
